Somatic mutation profile of tumor specimen MP2PRT-PAVGWA-TBP1-A (aliquot MP2PRT-PAVGWA-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVGWA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (868 days).
Specimen MP2PRT-PAVGWA-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e86e8b3a-e529-4dac-a2ab-ab309318c2da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVGWA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVGWA-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81a78685-980a-44c8-bddb-0008e6428430

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 40/776 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2
- AP3B2 | c.2593C>T p.R865W (on ENST00000261722; = p.R859W on NM_004644.5) | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.99); catalogued as rs201234574, COSV55607570; called by muse, mutect2
- ARHGEF18 | c.2638C>T p.R880W (on ENST00000359920 / NM_001130955.2; = p.R776W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/1286 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60470108; called by muse, mutect2
- SCML4 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 36/681 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1467901141; called by muse, mutect2
- THRB | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 13/479 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99769503; called by muse, mutect2
- TMEM200A | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 21/701 reads (3%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.629); called by muse, mutect2
- ADAMTS2 | c.2016C>T p.R672= | Silent (SNP) | VAF 26/880 reads (3%) | called by muse, mutect2
- TRABD2B | c.381C>T p.Y127= | Silent (SNP) | VAF 30/768 reads (4%) | catalogued as rs1317427021; called by muse, mutect2
